Gene-level copy-number profile of tumor specimen TCGA-AN-A0XW-01A from TCGA case TCGA-AN-A0XW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 36.2 years (13,208 days).
Specimen TCGA-AN-A0XW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.742b1f3f-a199-4dac-8d56-82db36855633.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0XW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 399 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8de3ea8d-e3b5-4167-960a-a2fa088a0828

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 525; copy number 1: 9,275; copy number 2: 42,731; copy number 3: 4,782; copy number 4: 1,410; copy number 5: 352; copy number 6: 202; copy number 7: 56; copy number 8: 290; copy number 9: 203; copy number 10: 82; copy number 11: 2; copy number 12: 98; copy number 14: 82; copy number 15: 33; copy number 18: 3; copy number 20: 2; copy number 22: 35; copy number 26: 61.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0XW-01A-11D-A107-01): tumor purity 0.51, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,501 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,448,131–100,292,769, 111 genes, copy number 5–8 (broad region; genes not listed).
- chr1:173,417,793–187,686,628, 259 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:189,666,149–208,270,667, 365 genes, copy number 6–12 (broad region; genes not listed).
- chr6:98,780,257–99,994,247, 19 genes, copy number 6: AL589826.1, AL589826.2, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2.
- chr6:101,181,257–102,070,083, 1 gene, copy number 20 (within-gene range 4–20): GRIK2.
- chr6:102,078,872–106,975,627, 50 genes, copy number 7–22: AP002530.1, AL357139.2, AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24.
- chr6:109,492,856–110,254,275, 6 genes, copy number 15 (within-gene range 1–15): AK9, FIG4, GPR6, AL590009.1, WASF1, CDC40.
- chr6:112,825,939–113,839,621, 13 genes, copy number 10: AL360085.1, RNU6-1163P, AL360015.1, FCF1P10, AL049695.1, SOCS5P5, AL589684.1, LINC02518, AL513123.1, RPS27AP11, LINC02541, FO393415.2, FO393415.1.
- chr11:67,266,473–68,130,518, 67 genes, copy number 10 (broad region; genes not listed).
- chr11:69,072,915–69,162,440, 1 gene, copy number 7 (within-gene range 3–7): AP003071.5.
- chr11:69,103,493–71,818,238, 76 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr11:76,435,559–79,441,030, 67 genes, copy number 9–26 (broad region; genes not listed).
- chr13:36,168,217–36,829,104, 14 genes, copy number 5: SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P, SPART, SPART-AS1, CCNA1, H2ACP1, SERTM1, GAPDHP34, TCEAL4P1, ARL2BPP3, NDE1P2, RFXAP.
- chr13:36,922,539–37,059,713, 6 genes, copy number 6: LAMTOR3P1, RPL29P28, EIF4A1P5, ALG5, EXOSC8, SUPT20H.
- chr13:38,349,849–38,373,935, 2 genes, copy number 9: UFM1, AL356863.1.
- chr13:86,725,500–86,726,053, 1 gene, copy number 10: TXNL1P1.
- chr17:36,486,629–37,056,871, 20 genes, copy number 5: ZNHIT3, RNA5SP439, MYO19, PIGW, GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5.
- chr17:37,140,611–37,163,139, 3 genes, copy number 5: AC244093.1, HMGB1P24, AC244093.2.
- chr17:38,297,023–38,605,952, 6 genes, copy number 7 (within-gene range 2–7): MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1.
- chr17:47,694,081–52,899,588, 201 genes, copy number 8–11 (broad region; genes not listed).
- chr17:53,353,427–53,439,721, 3 genes, copy number 6: AC005341.1, AC090079.1, AC090079.2.
- chr17:54,609,249–57,255,855, 45 genes, copy number 6–15: AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG, C17orf67, AC106858.1, DGKE, TRIM25, RNU6-1158P, AC015912.2, AC015912.1, MIR3614, AC015912.3, COIL, AC004584.1, AC004584.2, SCPEP1, AC004584.3, RNF126P1, AC007114.1, AKAP1, AC007114.2, AC003950.1, AC091181.2.
- chr17:57,600,856–60,666,280, 127 genes, copy number 8–14 (broad region; genes not listed).
- chr17:60,696,313–60,900,185, 6 genes, copy number 14: RN7SL606P, AC110602.1, Y_RNA, KRT18P61, HMGN1P28, RN7SL448P.
- chr20:11,234,170–13,821,580, 29 genes, copy number 7 (within-gene range 1–7): AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5.
- chr20:14,352,320–14,352,425, 1 gene, copy number 10: RNU6-228P.
- chr20:16,177,933–16,259,603, 2 genes, copy number 8 (within-gene range 1–8): AL161941.1, PPIAP17.

Autosomal genes at a single copy (total copy number 1): 9,275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
